Somatic mutation profile of cancer-model specimen HCM-BROD-0028-C71-85A (Adherent Cell Line, passage 11; aliquot HCM-BROD-0028-C71-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-BROD-0028-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.9 years (21,523 days).
Specimen HCM-BROD-0028-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62f59c0d-a10c-46ce-b39d-91c08d6eb83e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0028-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0028-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71843194-67a8-4b0a-b7bc-3c5d7879aaf2

The open-access MAF lists 104 somatic variants for this specimen: 70 protein-altering or splice-affecting, 17 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Intron 9, Frame Shift Del 6, Nonsense Mutation 5, In Frame Del 4, 5'Flank 3, 5'UTR 2, Splice Site 2, RNA 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 104/368 reads (28%) | catalogued as rs121908749, CM126469, CM940236, COSV99141556; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 164/591 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 124/127 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs397514560, CM1212354, COSV64293891, COSV64295025, COSV64300549; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SZT2 | c.4396C>T p.R1466* (on ENST00000634258 / NM_001365999.1; = p.R1409* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 187/187 reads (100%) | catalogued as rs766090540, COSV100987791; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGK | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.075); catalogued as rs180770509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 132/426 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62341659; called by muse, mutect2, varscan2
- CACNA1D | c.6209G>T p.G2070V (on ENST00000350061 / NM_001128840.3; = p.G2090V on NM_000720.4) | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV55460031; called by muse, mutect2, varscan2
- CCDC105 | c.875-2A>G p.X292_splice | Splice Site (SNP) | VAF 64/135 reads (47%) | catalogued as rs1329778624; called by muse, mutect2, varscan2
- DHX34 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553380305, COSV60898753; called by muse, mutect2, varscan2
- FAM83C | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 175/383 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs148042046; called by muse, mutect2, varscan2
- FMN1 | c.3639G>T p.K1213N (on ENST00000616417 / NM_001277313.2; = p.K990N on NM_001103184.4) | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57930588; called by muse, mutect2, varscan2
- FN1 | c.725T>G p.I242S | Missense Mutation (SNP) | VAF 206/448 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60556538; called by muse, mutect2, varscan2
- GCNT1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs368265529, COSV65058001; called by muse, mutect2, varscan2
- HAUS8 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs779654027; called by muse, mutect2, varscan2
- HRNR | c.6197C>G p.P2066R | Missense Mutation (SNP) | VAF 224/1231 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.054); catalogued as COSV64258034, COSV64260452; called by muse, mutect2, varscan2
- HS3ST6 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 152/307 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530650215, COSV99562847; called by muse, mutect2
- KAT7 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52013419; called by muse, mutect2, varscan2
- KCNC2 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs572944602; called by muse, mutect2, varscan2
- KRT86 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 171/604 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1257245996; called by muse, mutect2, varscan2
- MYLK | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 274/541 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs770980369, COSV100658752; called by muse, mutect2, varscan2
- NELFB | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 67/67 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs752724218; called by muse, mutect2, varscan2
- NFE2L3 | c.778_779del p.F260Lfs*14 | Frame Shift Del (DEL) | VAF 37/168 reads (22%) | catalogued as rs866076365; called by mutect2, pindel, varscan2
- PDZRN4 | c.953G>A p.R318K (on ENST00000402685 / NM_001164595.2; = p.R60K on NM_013377.4) | Missense Mutation (SNP) | VAF 122/278 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54216579; called by muse, mutect2, varscan2
- PHTF2 | c.1043G>A p.R348H (on ENST00000248550 / NM_001366089.1; = p.R310H on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs370027222; called by muse, mutect2, varscan2
- RNF17 | c.503C>A p.A168D | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55049034; called by muse, mutect2, varscan2
- TAT | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 281/619 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs150886066; called by muse, mutect2, varscan2
- TGFA | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 142/338 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782577747, COSV54912877; called by muse, mutect2, varscan2
- TGFBI | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 159/330 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV59354613; called by muse, mutect2, varscan2
- TRIM40 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 260/541 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV57156653, COSV57156976; called by muse, mutect2, varscan2
- TRPC7 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 94/202 reads (47%) | catalogued as rs1432751859, COSV100725651; called by muse, mutect2, varscan2
- ZCCHC2 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99502699; called by muse, mutect2, varscan2
- ZNF202 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 69/128 reads (54%) | catalogued as rs1321667568, COSV100279136; called by muse, mutect2, varscan2
- ZNF493 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV62749022; called by muse, varscan2
- AC090517.4 | c.1924_1929del p.C642_S643del | In Frame Del (DEL) | VAF 31/118 reads (26%) | called by mutect2, pindel, varscan2
- ACACA | c.3243del p.I1082Lfs*16 | Frame Shift Del (DEL) | VAF 99/259 reads (38%) | called by mutect2, pindel, varscan2
- CHADL | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 153/302 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DEF6 | c.858del p.N287Tfs*6 | Frame Shift Del (DEL) | VAF 84/176 reads (48%) | called by mutect2, varscan2
- FADS2 | c.909C>A p.Y303* | Nonsense Mutation (SNP) | VAF 130/276 reads (47%) | called by muse, mutect2, varscan2
- FLCN | c.856A>C p.M286L | Missense Mutation (SNP) | VAF 301/701 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRRS1 | c.992G>C p.G331A | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HERC1 | c.8112A>G p.I2704M | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- HRNR | c.3377C>G p.P1126R | Missense Mutation (SNP) | VAF 128/1604 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.151); called by muse, varscan2
- HSD17B4 | c.1556_1578+3del p.X519_splice (on ENST00000414835 / NM_001199291.3; = p.X494_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 34/198 reads (17%) | called by mutect2, pindel
- IGF1R | c.887T>C p.F296S | Missense Mutation (SNP) | VAF 162/330 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- IRS2 | c.3024dup p.E1009Rfs*63 | Frame Shift Ins (INS) | VAF 9/10 reads (90%) | called by mutect2, varscan2
- ITFG1 | c.664del p.L222* | Frame Shift Del (DEL) | VAF 47/136 reads (35%) | called by mutect2, pindel, varscan2
- LCE3E | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 289/627 reads (46%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRTM1 | c.559C>A p.H187N | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by mutect2, varscan2
- MEIOC | c.622T>G p.Y208D | Missense Mutation (SNP) | VAF 122/229 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MYO15A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 195/411 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- NETO1 | c.953T>G p.V318G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- OPRD1 | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 176/378 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCH2 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 129/241 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLXND1 | c.4133T>G p.L1378R | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- POTEG | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- POTEM | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RB1CC1 | c.1890_1892del p.Q630_T631delinsH | In Frame Del (DEL) | VAF 64/139 reads (46%) | called by mutect2, pindel, varscan2
- SLC8A2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 151/151 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SLCO5A1 | c.1226T>A p.V409D | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMTN | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 120/282 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SOCS7 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- STXBP5L | c.1991T>C p.V664A | Missense Mutation (SNP) | VAF 192/390 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- SULT1B1 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCEA2 | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 147/294 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TP53I13 | c.12_14del p.P6del | In Frame Del (DEL) | VAF 122/298 reads (41%) | called by pindel, varscan2
- TTC31 | c.1214del p.Q405Rfs*58 | Frame Shift Del (DEL) | VAF 120/330 reads (36%) | called by mutect2, pindel, varscan2
- USP24 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- WRAP53 | c.1641del p.I548Yfs*? | Frame Shift Del (DEL) | VAF 86/222 reads (39%) | called by mutect2, pindel, varscan2
- ZNF292 | c.3130C>G p.P1044A | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZSWIM3 | c.2029_2031del p.L677del | In Frame Del (DEL) | VAF 63/142 reads (44%) | called by mutect2, pindel, varscan2
- ATP5MC2 | c.321T>C p.S107= | Silent (SNP) | VAF 224/503 reads (45%) | catalogued as COSV58600965; called by muse, mutect2, varscan2
- C1QL2 | c.111T>A p.T37= | Silent (SNP) | VAF 104/213 reads (49%) | called by muse, mutect2, varscan2
- DISP2 | c.4137T>C p.N1379= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs771631656; called by muse, mutect2, varscan2
- DRD5 | c.555G>A p.A185= | Silent (SNP) | VAF 100/197 reads (51%) | catalogued as rs1461653045, COSV100431960; called by muse, mutect2, varscan2
- ERO1A | c.696T>G p.T232= | Silent (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- GRIN2B | c.1080G>A p.P360= | Silent (SNP) | VAF 190/432 reads (44%) | catalogued as rs201952040, COSV74204867; ClinVar: likely benign; called by muse, mutect2, varscan2
- GTF2F1 | c.825A>C p.S275= | Silent (SNP) | VAF 143/291 reads (49%) | called by muse, mutect2, varscan2
- GTF3C3 | c.165A>G p.S55= | Silent (SNP) | VAF 83/163 reads (51%) | catalogued as rs375698779; called by muse, mutect2, varscan2
- LCA5 | c.729G>A p.S243= | Silent (SNP) | VAF 60/60 reads (100%) | catalogued as rs756379569, COSV63970954; called by muse, mutect2
- OR6P1 | c.690G>A p.T230= | Silent (SNP) | VAF 352/693 reads (51%) | catalogued as rs531306117, COSV58109054; called by muse, mutect2, varscan2
- RNF26 | c.513T>C p.D171= | Silent (SNP) | VAF 66/132 reads (50%) | called by muse, mutect2, varscan2
- RTN1 | c.1866C>T p.S622= | Silent (SNP) | VAF 308/626 reads (49%) | catalogued as rs772270786, COSV50721100; called by muse, mutect2, varscan2
- SLC6A14 | c.139C>T p.L47= | Silent (SNP) | VAF 91/92 reads (99%) | catalogued as COSV100903220; called by muse, mutect2, varscan2
- TENM2 | c.477C>T p.N159= | Silent (SNP) | VAF 202/419 reads (48%) | catalogued as rs763730897, COSV72862642; called by muse, mutect2, varscan2
- TGIF2LX | c.330G>A p.P110= | Silent (SNP) | VAF 324/324 reads (100%) | catalogued as rs1293739273, COSV99383324; called by muse, mutect2, varscan2
- TJP3 | c.1137C>T p.P379= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs769361845, COSV53662741; called by muse, mutect2, varscan2
- XPO6 | c.1473G>A p.R491= | Silent (SNP) | VAF 192/382 reads (50%) | called by muse, mutect2, varscan2
- ARFRP1 | c.417+542_417+543insA | Intron (INS) | VAF 166/360 reads (46%) | catalogued as rs386394225; called by mutect2, varscan2
- DCXR | c.448+12dup | Intron (INS) | VAF 383/919 reads (42%) | called by mutect2, pindel, varscan2
- GLT1D1 | c.68+10522C>T | Intron (SNP) | VAF 22/47 reads (47%) | catalogued as rs954687956; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457629 A>G | 5'Flank (SNP) | VAF 84/569 reads (15%) | catalogued as rs1312171368; called by muse, mutect2
- KCNAB2 | c.1014+47G>A | Intron (SNP) | VAF 150/150 reads (100%) | called by muse, mutect2, varscan2
- LIMA1 | c.1141-3359T>A | Intron (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- LINC02740 | n.286G>A | RNA (SNP) | VAF 114/293 reads (39%) | catalogued as rs965426550; called by muse, mutect2, varscan2
- MARK3 | c.1872-39T>G | Intron (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- NDUFV2 | c.-2C>T | 5'UTR (SNP) | VAF 147/331 reads (44%) | catalogued as rs528658653, COSV100571724; called by muse, mutect2, varscan2
- OR7D1P | n.525G>A | RNA (SNP) | VAF 132/281 reads (47%) | catalogued as rs539111941; called by muse, mutect2, varscan2
- PTGFRN | c.-135C>T | 5'UTR (SNP) | VAF 159/159 reads (100%) | catalogued as rs904326120; called by muse, mutect2, varscan2
- RADX | c.1573+31A>T | Intron (SNP) | VAF 76/76 reads (100%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790930 C>T | 5'Flank (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- RNU6-467P | chr17:20321375 T>C | 5'Flank (SNP) | VAF 131/257 reads (51%) | called by muse, mutect2, varscan2
- RTN3 | c.*151C>T | 3'UTR (SNP) | VAF 37/65 reads (57%) | catalogued as rs761755900; called by muse, mutect2, varscan2
- TFR2 | c.615-28C>T | Intron (SNP) | VAF 140/387 reads (36%) | catalogued as rs745475672; called by muse, mutect2, varscan2
- TSC22D2 | c.2030+15114G>T | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
